Somatic mutation profile of tumor specimen TCGA-A2-A04N-01A (aliquot TCGA-A2-A04N-01A-11D-A10Y-09) from TCGA case TCGA-A2-A04N, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.1 years (24,155 days).
Specimen TCGA-A2-A04N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07407960-d958-4957-bb73-b455873db811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04N-10A (Blood Derived Normal), aliquot TCGA-A2-A04N-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b51f3d8-a8f7-45ae-8a88-2646619b1fed

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 30, Silent 11, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV56091519; called by muse, mutect2, varscan2
- AQR | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs201358907, COSV99334021; called by muse, mutect2, varscan2
- CD55 | c.398del p.Y133Sfs*11 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as COSV58577841; called by mutect2, pindel, varscan2
- COL6A6 | c.3036G>T p.Q1012H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62034581; called by muse, mutect2, varscan2
- ELP6 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs545060366, COSV56133007; called by muse, mutect2, varscan2
- EML5 | c.1673A>T p.K558I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61350998; called by muse, mutect2, varscan2
- GDPD1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs1474150050, COSV52384027; called by muse, mutect2, varscan2
- KIF16B | c.1243-1G>T p.X415_splice | Splice Site (SNP) | VAF 29/202 reads (14%) | catalogued as COSV61712395; called by muse, mutect2, varscan2
- MAGEE2 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs775467404, COSV100973186, COSV64898345; called by muse, mutect2, varscan2
- MAP3K1 | c.1490del p.S497Ffs*60 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as COSV68126494; called by mutect2, pindel, varscan2
- MAP3K1 | c.4036_4038del p.V1346del | In Frame Del (DEL) | VAF 20/127 reads (16%) | catalogued as COSV68122766; called by mutect2, pindel, varscan2
- MAP3K1 | c.4121A>G p.N1374S | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68125267; called by muse, mutect2, varscan2
- MAP3K1 | c.4310G>T p.C1437F | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68122771, COSV68126501; called by muse, mutect2, varscan2
- MYO3A | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56344747; called by muse, mutect2, varscan2
- MYO5B | c.3526A>C p.K1176Q | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53228297; called by muse, mutect2, varscan2
- NEUROD6 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs371375986; called by muse, mutect2, varscan2
- OR10H1 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 73/393 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as rs371707981; called by muse, varscan2
- OR1J4 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs183115276; called by muse, mutect2, varscan2
- OR4L1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367946088; called by muse, mutect2, varscan2
- PCNT | c.4901C>T p.P1634L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV64032015; called by muse, mutect2, varscan2
- PIK3C3 | c.1826C>A p.A609D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV56283391; called by muse, mutect2, varscan2
- PRKAG3 | c.1405T>C p.S469P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52103414; called by muse, mutect2, varscan2
- RAD9A | c.387T>A p.C129* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100334965; called by muse, mutect2, varscan2
- REG1B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs749277780, COSV59307427; called by muse, mutect2, varscan2
- RNFT2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1303374273, COSV54338473; called by muse, mutect2, varscan2
- SCLT1 | c.865A>T p.I289L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55411355; called by muse, mutect2, varscan2
- SCN2A | c.2596A>C p.T866P | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51852485; called by muse, mutect2, varscan2
- TCF12 | c.1435A>C p.N479H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV51019079; called by muse, mutect2, varscan2
- TRAF5 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99807425; called by muse, mutect2, varscan2
- TSNARE1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.677); catalogued as COSV56181920; called by muse, mutect2, varscan2
- UNC45B | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs768111560, COSV52099722; called by muse, mutect2, varscan2
- UTP14A | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV100928966; called by muse, mutect2
- VRTN | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368643849, COSV56443158; called by muse, mutect2, varscan2
- ZNF791 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV58482392; called by muse, mutect2, varscan2
- XPO1 | c.1174_1175insTCTCTCTG p.P392Lfs*31 | Frame Shift Ins (INS) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- DHX32 | c.1782T>C p.I594= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV52942871; called by muse, mutect2, varscan2
- FAM13A | c.3057T>C p.D1019= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as rs1311303557, COSV52011124; called by muse, mutect2, varscan2
- KANSL1L | c.528G>A p.E176= | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as COSV55992073, COSV55996194; called by muse, mutect2, varscan2
- KIRREL3 | c.2115G>A p.E705= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV69385964; called by muse, mutect2, varscan2
- LAMA1 | c.789C>T p.D263= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV67542946; called by muse, mutect2, varscan2
- RBM38 | c.285G>A p.P95= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100654838; called by muse, mutect2
- SLC7A8 | c.699C>T p.L233= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs768855621, COSV57554077; called by muse, mutect2, varscan2
- TG | c.793C>T p.L265= | Silent (SNP) | VAF 44/488 reads (9%) | catalogued as COSV99601138; called by muse, mutect2
- TOX2 | c.1452G>A p.S484= (on ENST00000358131 / NM_001098798.2; = p.S460= on NM_032883.3) | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as rs754898188, COSV57893505; called by muse, mutect2, varscan2
- TTN | c.6177C>A p.I2059= (on ENST00000591111; = p.I2013= on NM_003319.4) | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as COSV60278939, COSV60401714; called by muse, mutect2, varscan2
- ZNF461 | c.1581C>T p.C527= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs561974097, COSV100831429, COSV64454901; called by muse, mutect2, varscan2
